MMRF case MMRF_2085 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5008c4c3-f17f-4d78-939f-2d94e07ad6ef

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 512 days (1.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.7 years (27,278 days); Days to last known disease status: 512 days (1.4 years); Days to last follow up: 512 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 9 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 96 days; Days to treatment end: 96 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 96 days; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 122 days; Days to treatment end: 141 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 234 days; Days to treatment end: 417 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 418 days (1.1 years); Days to treatment end: 435 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 512.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 1.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 123 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.01 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 9.19 mmol/L.
- Day 72 (ECOG 2): M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25.4 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.97 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 31 g/L; Total Protein 5.4 g/dL; Glucose 8.75 mmol/L.
- Day 152 (ECOG 2): M Protein 0.22 g/dL; Immunoglobulin G 3.96 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 6.3 µg/mL; Hemoglobin 6.51 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 8.1 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 17.1 mmol/L; Calcium 2.33 mmol/L; Total Protein 4.8 g/dL; Glucose 10.9 mmol/L.
- Day 243 (ECOG 3): M Protein 0.5 g/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 6.35 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 12.7 ×10⁹/L; Absolute Neutrophil 10.4 ×10⁹/L; Platelets 485 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.05 mmol/L; Albumin 28 g/L; Total Protein 5.3 g/dL; Glucose 4.4 mmol/L.
- Day 360 (ECOG 3): M Protein 0.93 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 53.8 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 6.97 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 7.31 ×10⁹/L; Platelets 347 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.55 mmol/L; Albumin 30 g/L; Total Protein 6.1 g/dL; Glucose 4.95 mmol/L.
- Day 435 (ECOG 4): M Protein 0.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.707 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 46.7 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 7.66 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 52.2 µmol/L; Albumin 32 g/L; Total Protein 6 g/dL; Glucose 6.71 mmol/L.

Other clinical attributes
- Day -17: Weight: 100 kg; Height: 163 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_2085_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 152 days.
- Sample MMRF_2085_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 152 days.
- Sample MMRF_2085_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 435 days (1.2 years).
